MMRF case MMRF_2516 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/41f3360a-b125-4031-8d28-693537109b4c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.9 years (24,805 days); ISS stage: I; Days to last known disease status: 701 days (1.9 years); Days to last follow up: 701 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 9 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 245 days; Days to treatment end: 259 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20: M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 259 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 8.14 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.81 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.6 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 1.28 mg/dL.
- Day 64 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.46 mg/dL; Immunoglobulin G 4.05 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 1.87 µg/mL; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 4.94 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 5.12 mmol/L.
- Day 154 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 9.8 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.96 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 238: M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.61 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 6.66 mmol/L.
- Day 329 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.48 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.
- Day 441 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 1.06 g/L; Beta 2 Microglobulin 1.29 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.16 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.56 mmol/L.
- Day 533 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.98 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 617 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 1.14 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 5.28 mmol/L.
- Day 701 (ECOG 1): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 1.04 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.23 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -20: Weight: 78 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2516_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2516_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
